Somatic mutation profile of tumor specimen TCGA-25-1323-01A (aliquot TCGA-25-1323-01A-01W-0494-09) from TCGA case TCGA-25-1323, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.8 years (26,602 days).
Specimen TCGA-25-1323-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d5b5a92-0b73-4166-b44a-86ec8ac4d8fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-1323-10A (Blood Derived Normal), aliquot TCGA-25-1323-10A-01W-0494-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cf75970-63c1-442d-beb8-52f5d6de0f68

The open-access MAF lists 84 somatic variants for this specimen: 70 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 60, Silent 14, Nonsense Mutation 5, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 34/44 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs770041154, COSV100903045; called by muse, mutect2, varscan2
- AKR1C2 | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV101060391; called by muse, mutect2, varscan2
- ALDH1L1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99856564; called by mutect2, varscan2
- ARHGAP5 | c.3054G>C p.E1018D | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100565063; called by muse, mutect2, varscan2
- ARID4A | c.3373C>G p.P1125A | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100794070; called by muse, mutect2, varscan2
- BICD1 | c.2841-1G>C p.X947_splice | Splice Site (SNP) | VAF 13/83 reads (16%) | catalogued as rs755634331, COSV99862046; called by muse, mutect2, varscan2
- BIRC6 | c.12562G>C p.V4188L | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV101427948; called by muse, mutect2
- C2CD3 | c.4735C>T p.H1579Y | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV58095623; called by muse, mutect2
- CAPZA1 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as rs753793163, COSV54144163, COSV99037013; called by muse, mutect2, varscan2
- CCR1 | c.293A>T p.D98V | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV99946657; called by muse, mutect2, varscan2
- CD37 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.335); catalogued as COSV100114895, COSV60545061; called by muse, mutect2, varscan2
- CDR2 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV99193487; called by muse, mutect2, varscan2
- CNTNAP2 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.057); catalogued as rs1396997189, COSV100663504, COSV62227448; called by muse, mutect2
- COL17A1 | c.1727G>T p.G576V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100793075; called by muse, mutect2, varscan2
- CRX | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99704374; called by mutect2, varscan2
- CSMD3 | c.1633G>T p.V545L (on ENST00000297405 / NM_001363185.1; = p.V441L on NM_052900.3) | Missense Mutation (SNP) | VAF 51/431 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV99826970; called by muse, mutect2, varscan2
- DCSTAMP | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99886165; called by muse, mutect2, varscan2
- DMD | c.6210A>T p.E2070D | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.966); catalogued as COSV100818450; called by muse, mutect2, varscan2
- EIF2AK3 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57547781; called by muse, mutect2, varscan2
- EPS8L3 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV100719671, COSV62610113; called by muse, mutect2
- FAM107A | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs757345690, COSV100723927; called by muse, mutect2, varscan2
- FAP | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs1174167963, COSV51858787; called by muse, mutect2, varscan2
- FBXL2 | c.656C>A p.S219* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | catalogued as COSV99371705; called by muse, mutect2
- GATA1 | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100936716; called by muse, mutect2, varscan2
- GIMAP8 | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1423197632, COSV100217358; called by muse, mutect2
- HCLS1 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 49/848 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV100100412; called by muse, mutect2
- HECW1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67824006; called by muse, mutect2, varscan2
- JAK3 | c.1651A>G p.T551A | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV71687550; called by muse, mutect2
- LENG8 | c.1323_1324insT p.D442* | Frame Shift Ins (INS) | VAF 7/39 reads (18%) | catalogued as COSV100457200; called by mutect2, pindel, varscan2
- M1AP | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 26/128 reads (20%) | catalogued as COSV99303754, COSV99304191; called by muse, mutect2, varscan2
- MACF1 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 18/156 reads (12%) | catalogued as COSV100482895; called by muse, mutect2, varscan2
- MARK2 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158181; called by muse, mutect2
- MBL2 | c.718C>A p.H240N | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV64759286, COSV64759557; called by muse, varscan2
- MCM7 | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 10/195 reads (5%) | catalogued as COSV57995477; called by muse, mutect2
- MED13L | c.5707C>T p.R1903C | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99928022; called by muse, mutect2, varscan2
- NBEA | c.4916C>A p.S1639* | Nonsense Mutation (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100077371; called by muse, mutect2
- NEB | c.1063A>T p.N355Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99416216; called by muse, mutect2, varscan2
- NETO1 | c.156del p.F53Lfs*20 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | catalogued as COSV55006517, COSV55014459; called by mutect2, pindel
- NLRP4 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs750811265, COSV56722494; called by muse, mutect2
- NRXN1 | c.1688T>A p.I563K | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV100453693; called by muse, mutect2
- NUP85 | c.1912T>C p.S638P | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV55455773; called by muse, mutect2, varscan2
- OR4D10 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as rs563150769, COSV101596997; called by muse, mutect2
- OR51A4 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs763198309, COSV66748968; called by muse, mutect2, varscan2
- OR5AS1 | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs1402450544, COSV100546172; called by muse, mutect2
- PCOLCE2 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs752616266, COSV56002523; called by muse, mutect2, varscan2
- PDCD7 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1566972865, COSV99200126; called by muse, mutect2, varscan2
- PRB2 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 30/563 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as rs768086724; called by muse, mutect2
- PSMD4 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100924649, COSV64394112; called by muse, mutect2
- RGS4 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 44/768 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV100905522; called by muse, mutect2
- SCEL | c.1253C>A p.P418Q (on ENST00000349847 / NM_144777.3; = p.P398Q on NM_003843.4) | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100582644; called by muse, mutect2
- SCYL2 | c.2483A>G p.K828R | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV100675064; called by muse, mutect2
- SMTN | c.2545G>A p.G849R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs774591858, COSV100294065, COSV100294077; called by muse, mutect2, varscan2
- SRP68 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777477411, COSV100325988; called by muse, mutect2, varscan2
- STAT4 | c.1677T>A p.D559E | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV100635981; called by muse, mutect2
- TAF4B | c.1964T>A p.L655H | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99299849; called by muse, mutect2, varscan2
- THSD7A | c.4930C>A p.L1644M | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.961); catalogued as COSV101349161; called by muse, mutect2, varscan2
- TM6SF2 | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99363658; called by muse, mutect2, varscan2
- TNF | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV101403146; called by muse, mutect2, varscan2
- TTC13 | c.1575G>C p.K525N | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.144); catalogued as COSV100792863; called by muse, mutect2
- USH2A | c.15190C>A p.Q5064K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs1448248120; called by muse, mutect2
- VTI1A | c.342+2T>G p.X114_splice | Splice Site (SNP) | VAF 11/71 reads (15%) | catalogued as COSV101261074; called by muse, mutect2, varscan2
- WSCD2 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs1379043488, COSV54578928; called by muse, mutect2, varscan2
- XPO4 | c.2329C>T p.Q777* | Nonsense Mutation (SNP) | VAF 7/112 reads (6%) | catalogued as COSV55010206; called by muse, mutect2
- ZNF502 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs767905551, COSV56072388; called by muse, mutect2, varscan2
- ZSCAN20 | c.2357G>A p.R786K | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV63682136, COSV63682306; called by muse, mutect2
- ELOVL3 | c.585dup p.K196Qfs*83 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by pindel, varscan2
- MBL2 | c.719A>T p.H240L | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by mutect2, varscan2
- MXRA5 | c.1678A>T p.R560W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, varscan2
- PDS5B | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2
- ASB16 | c.246C>T p.A82= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs780782857, COSV99518771; called by muse, mutect2, varscan2
- BSCL2 | c.738C>T p.L246= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99627999; called by muse, mutect2, varscan2
- CDK2 | c.492G>T p.V164= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99906670; called by muse, mutect2, varscan2
- CYP4V2 | c.393T>G p.L131= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV101114760; called by muse, mutect2, varscan2
- FZD3 | c.1215A>C p.P405= | Silent (SNP) | VAF 24/174 reads (14%) | catalogued as COSV53537624, COSV99527897; called by muse, mutect2, varscan2
- GIMAP8 | c.750C>T p.V250= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV100217356; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1911C>G p.T637= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100145558; called by muse, mutect2, varscan2
- LCMT2 | c.1293G>T p.L431= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1394121867, COSV99979939; called by muse, mutect2, varscan2
- MAGI3 | c.2784C>T p.V928= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV100288258; called by muse, mutect2, varscan2
- OR8K1 | c.117C>T p.I39= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as COSV54403351; called by muse, mutect2, varscan2
- PDZD2 | c.3306G>A p.G1102= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs150340042; called by mutect2, varscan2
- PPP1R3A | c.253T>C p.L85= | Silent (SNP) | VAF 22/216 reads (10%) | catalogued as COSV99492143; called by muse, mutect2
- SPINK5 | c.888C>T p.L296= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as COSV99806223; called by muse, mutect2, varscan2
- UGT1A3 | c.381T>G p.S127= | Silent (SNP) | VAF 51/241 reads (21%) | catalogued as COSV100529777; called by muse, mutect2, varscan2
